FM case AD3963 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/0aa8b854-e8a1-47b0-a017-f00edc24830c

Female, 72.8 years: Large cell neuroendocrine carcinoma (ICD-O-3 8013/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
